Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02W, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02W-01A (Primary Tumor).

TCGA #:

Internal Sample ID: _____

Diagnosis:

This is a moderately differentiated adenocarcinoma of the sigmoid colon with histopathological grade G2 differentiation, with erosions of the inner tumor surface, with peritumorous, chronic recurrent concomitant inflammation, with tumor infiltration of the parietal layers of the sigmoid colon extending to the outer layers of the tunica muscularis, with chronic lymphadenitis of the tumor-free lymph nodes (0/12) and tumor-free overview sections from the resection margins and from the region of the vascular ligature.

According to these section preparations, the tumor spread of the sigmoid colon carcinoma corresponds to a tumor stage of pT2, pN0, MX, R0.

1CD-0-3
adenocarcinoma, NOS 8140/3
Site: Sigmoid colon C18.7 Lu 3/30/11

Source: NCI Genomic Data Commons file 0bf5c362-ee85-444a-b130-b7e790269156 (TCGA-AA-A02W.257FBF57-5DB1-44D5-994D-64EFD1CA4E57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).